Surgical pathology report (de-identified scan), TCGA case TCGA-KC-A7FA, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Cornell Medical College, specimen TCGA-KC-A7FA-01A (Primary Tumor).

[page 1 of 4]
Patient:
MRN:
DOB:
SEX: Male

SURGICAL PATHOLOGY, COMPREHENSIVE

Status: Final result Not Released

Surgical Pathology

Inquiry:
Fax:

Surgical Pathology Report

Specimen Date:
In Lab Date:
Report Date:

Patient:

MRN:

Encounter #:
Location:
Age/ Sex:

CLINICAL INFORMATION:
Prostate cancer.

INTRAOPERATIVE DIAGNOSIS:

A. Through E. Frozen section diagnosis: Soft tissue only.

Reported to:

CCF ICCO-3
Adenocarcinoma, Gleason
path 8146/3
Adenocarcinoma NOS 8146/3

Site Prostate NOS
661.9
JW 9/26/13

GROSS DESCRIPTION:

A. Received fresh, the specimen is labeled "posterior apical" and consists of a 0.2 x 0.2 x 0.1 cm piece of tan soft tissue. 100% submitted for frozen section. Summary of sections: A1FSC.

B. Received fresh, the specimen is labeled "left posterior para-apical" and consists of a 0.2 x 0.2 x 0.1 cm piece of tan soft tissue. 100% submitted for frozen section. Summary of section: B1 FSC.

C. Received fresh, the specimen is labeled "left mid posterior lateral" and consists of a 0.2 x 0.2 x 0.1 cm piece of tan soft tissue surface which is submitted for frozen section. Summary of sections: C1 FSC.

D. Received fresh, the specimen is labeled "right posterior para-apical" and consists of a 0.2 x 0.2 x 0.1 cm piece of tan soft tissue. 100% submitted for frozen section. Summary of sections: D1FSC.

E. Received fresh, the specimen is labeled "left anterior apical" and consists of a 0.2 x 0.2 x 0.1 cm piece of tan soft tissue. 100% submitted for frozen section. Summary of sections: E1FSC.

[page 2 of 4]
F. Received fresh, the specimen is labeled "prostate gland and seminal vesicles", and consists of a 40.5g prostatectomy specimen including a 4.6 x 4.2 x 4.0 cm prostate, a 4.0 x 1.9 x 1.1 cm left seminal vesicle, a 4.0 x 0.6 x 0.5 cm left vas deferens, a 4.5 x 1.5 x 1.5 cm right seminal vesicle, and a 4.0 x 0.6 x 0.6 cm right vas deferens. The right side of the specimen is inked green and the left side is inked black. The seminal vesicle base, bladder neck and apical margins are shaved and submitted. The prostate is serially sectioned from the apex to base with sections designated from A to G respectively. Section B is submitted for research. On sectioning, multiple nodular and cystic areas are seen. The remainder of the prostate is submitted entirely. Summary of sections: F1-RSV and LSV, F2-right anterior base, F3-right posterior base, F4-left anterior base, F5-left posterior base, F6-right anterior apex, F7-right posterior apex, F8-left anterior apex, F9-left posterior apex, F10-ARA, F11-ARP, F12-ALA (missing ink), F13-ALP (missing ink), F14-CRA, F15-CRP (missing ink), F16-CLA, F17-CLP, F18-DRA, F19-DRP, F20-DLA, F21-DLP, F22-ERA, F23-ERP, F24-ELA, F25-ELP, F26-FRA, F27-FRP, F28-FLA, F29-FLP.

G. Received fresh, assessment is labeled "pelvic lymph nodes" and consists of a 5.0 x 5.0 x 1.5 cm aggregate of lymph nodes with attached yellow fatty tissue. The lymph nodes are submitted entirely. Summary of sections: G1-G6.

H. Received fresh, specimen is labeled "anterior prostatic fat" and consists of a 2.5 x 2.0 x 1.2 cm aggregate of lymph nodes and fatty tissue. 100% submitted. Summary of section: H1.

DIAGNOSIS:

- A. Prostate, posterior apical margin (biopsy):
Fibromuscular tissue and nerve.
No prostatic glands or carcinoma identified.
- B. Prostate, left posterior para-apical margin (biopsy):
Fibromuscular tissue.
No prostatic glands or carcinoma identified.
- C. Prostate, left mid posterior lateral margin (biopsy):
Fibromuscular tissue and nerve.
No prostatic glands or carcinoma identified.
- D. Prostate, right posterior para-apical margin (biopsy):
Fibromuscular tissue and nerve.
No prostatic glands or carcinoma identified.
- E. Prostate, left anterior apical (biopsy):
Fibromuscular tissue and nerve.
No prostatic glands or carcinoma identified.
- F. Prostate gland and seminal vesicles (radical prostatectomy):
Prostatic adenocarcinoma, Gleason score 7(3+4),
bilateral.
- Extraprostatic extension, focal, left posterior mid (F17).
- Seminal vesicles and all surgical margins are negative for tumor.

Please see pathologic staging summary.

Note: The tumor is present in the following sections: F6, F8, F10, F14, F15-17, F20-F22.

[page 3 of 4]
G Lymph nodes, pelvic (excision):
Nineteen lymph nodes, negative for metastatic carcinoma
(0/19).

H Lymph nodes, anterior prostate (excision):
Five lymph nodes, negative for metastatic carcinoma
(0/5).

SYNOPTIC DIAGNOSIS:

Histologic Type: (conventional, not otherwise specified)	Adenocarcinoma
	Primary Pattern: Grade 3
	Secondary Pattern: Grade 4
	Total Gleason Score: 7
Tumor Quantitation: prostatic tissue involved by tumor: 10%	Proportion (percent) of
Pathologic Staging (pTNM): extension	pT3a: Extraprostatic
node metastasis	pN0: No regional lymph
nodes examined: 24	Number of regional lymph
nodes involved: 0	Number of regional lymph
cannot be assessed	pMX: Distant metastasis
Margins: invasive carcinoma	Margins uninvolved by
Extraprostatic Extension:	Present
	Unifocal present
Seminal Vesicle Invasion:	Absent
Perineural Invasion:	Present
Venous (Large Vessel) Invasion (V):	Absent
Lymphatic (Small Vessel) Invasion (L):	Absent
Additional Pathologic Findings: intraepithelial neoplasia (PIN)	High-grade prostatic
hyperplasia	Benign prostatic

** Electronically Signed Out **

Attending Pathologist
The attending pathologist whose signature appears on this
report has reviewed the diagnostic slides, and has edited
the gross and microscopic portions of the report in rendering the
final diagnosis.

ICD9 Codes: A-H: 185

Billing Codes: A-E: ;

(Inpatient)

F;

G-H;

SNOMED

Slides: A-2, B-2, C-2, D-2, E-2, F-36, G-5, H-1

Resulting Agency

Specimen Collected:

Last Resulted:

[page 4 of 4]
Order Information Lab Collection Information, Order Information, Order Providers

Source: NCI Genomic Data Commons file 79af5a94-23a2-47a0-89d2-ed48ba9ed9d8 (TCGA-KC-A7FA.CF60F3B8-9AF5-4D51-8E17-BC7940235E96.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).